Gene-level copy-number profile of tumor specimen TCGA-2F-A9KT-01A from TCGA case TCGA-2F-A9KT, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-2F-A9KT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ffff2171-177c-45d5-98a9-fa4206c7c181.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2F-A9KT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/edda993c-a1cf-4cff-8b34-9c302336784f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 61; copy number 2: 11,628; copy number 3: 10,477; copy number 4: 35,120; copy number 5: 822; copy number 6: 588; copy number 7: 771; copy number 8: 76; copy number 9: 24; copy number 10: 48; copy number 11: 21; copy number 12: 15; copy number 13: 8; copy number 14: 27; copy number 15: 47; copy number 20: 28; copy number 22: 22; copy number 26: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2F-A9KT-01A-11D-A38F-01): tumor purity 0.41, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 269 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:23,013,048–23,689,386, 8 genes, copy number 13: AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1.
- chr7:17,299,295–17,558,909, 4 genes, copy number 10 (within-gene range 5–10): AC019117.3, SNORA63, AC019117.2, AC019117.1.
- chr8:41,653,220–41,896,762, 1 gene, copy number 9 (within-gene range 3–9): ANK1.
- chr8:41,803,349–42,207,709, 11 genes, copy number 9: Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT.
- chr20:31,968,151–32,608,893, 25 genes, copy number 14: XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1.
- chr20:37,178,410–38,033,461, 18 genes, copy number 9–12: RPN2, GHRH, MANBAL, AL034422.1, SRC, RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1.
- chr20:41,402,083–48,849,458, 202 genes, copy number 9–26 (within-gene range 3–26) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 61. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
